Somatic mutation profile of tumor specimen C3N-01806-01 (aliquot CPT0115680009) from CPTAC case C3N-01806, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 57.4 years (20,979 days).
Specimen C3N-01806-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d6b91a3-accc-4fa1-b447-a9be0f6befa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01806-31 (Blood Derived Normal), aliquot CPT0116370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9576390a-2412-4cbd-b83b-ef298c9507d1

The open-access MAF lists 84 somatic variants for this specimen: 58 protein-altering or splice-affecting, 15 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 15, Intron 5, Frame Shift Del 5, Nonsense Mutation 4, Frame Shift Ins 2, 5'UTR 2, 5'Flank 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 97/540 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131690962, CM003060, COSV104374386, COSV56542402, COSV56545166; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CA4 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 67/593 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1017895117; called by muse, mutect2, varscan2
- CEBPZ | c.1523T>C p.I508T | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs752087907, COSV50018005; called by muse, mutect2
- GALR1 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV55317205; called by muse, mutect2, varscan2
- GPR20 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as rs147333228, COSV66683872; called by muse, mutect2, varscan2
- HDGFL1 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs1315721143; called by muse, mutect2, varscan2
- MRC2 | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV57641994; called by muse, mutect2, varscan2
- PLA2G4A | c.1601del p.I534Nfs*14 | Frame Shift Del (DEL) | VAF 40/317 reads (13%) | catalogued as COSV66556580; called by mutect2, pindel, varscan2
- QRICH2 | c.3823G>A p.E1275K | Missense Mutation (SNP) | VAF 41/409 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs199760483; called by muse, varscan2
- RANBP17 | c.2683C>G p.L895V | Missense Mutation (SNP) | VAF 33/342 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV66652025; called by muse, mutect2
- RAX | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 70/580 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56875483; called by muse, mutect2, varscan2
- SLC7A9 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 57/559 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1248141788, CD010662; called by muse, mutect2, varscan2
- SLC9A9 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1365733195; called by muse, mutect2, varscan2
- SOX12 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.081); catalogued as rs1337191150; called by muse, mutect2, varscan2
- SV2C | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.646); catalogued as COSV59221947; called by muse, mutect2, varscan2
- TCF19 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52565210; called by muse, mutect2, varscan2
- TUBA3C | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV67139540; called by muse, mutect2, varscan2
- CACNA1I | c.3071A>T p.E1024V | Missense Mutation (SNP) | VAF 65/608 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CASZ1 | c.1511G>C p.S504T | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- CBY2 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- CCDC40 | c.2720T>A p.I907N | Missense Mutation (SNP) | VAF 73/551 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CENPB | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 40/538 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.029); called by muse, mutect2
- CHD8 | c.1658C>A p.S553* (on ENST00000646647 / NM_001170629.2; = p.S274* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 9/238 reads (4%) | called by muse, mutect2
- CLIP4 | c.343T>A p.C115S | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNOT10 | c.1892del p.P631Lfs*14 | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | called by mutect2, pindel, varscan2
- COL6A1 | c.1706G>C p.G569A | Missense Mutation (SNP) | VAF 57/502 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CTSL | c.492G>C p.Q164H | Missense Mutation (SNP) | VAF 58/465 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP2J2 | c.322T>A p.F108I | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- DCAF4 | c.205T>A p.F69I | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- DHX38 | c.1435dup p.M479Nfs*11 | Frame Shift Ins (INS) | VAF 34/252 reads (13%) | called by mutect2, pindel, varscan2
- DUT | c.679del p.Y227Ifs*4 (on ENST00000331200 / NM_001025248.2; = p.Y139Ifs*4 on NM_001948.4) | Frame Shift Del (DEL) | VAF 25/212 reads (12%) | called by mutect2, pindel, varscan2
- EYS | c.4090G>A p.D1364N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GFPT1 | c.1492A>G p.S498G (on ENST00000357308 / NM_001244710.2; = p.S480G on NM_002056.4) | Missense Mutation (SNP) | VAF 75/502 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HDLBP | c.638T>A p.L213* | Nonsense Mutation (SNP) | VAF 60/330 reads (18%) | called by muse, mutect2, varscan2
- HIC1 | c.1937C>T p.P646L (on ENST00000322941 / NM_001098202.1; = p.P627L on NM_006497.4) | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); called by muse, mutect2
- INTU | c.1275T>G p.I425M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- MAP3K12 | c.1285T>C p.Y429H | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARS1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.029); called by muse, mutect2
- MMP9 | c.769A>T p.S257C | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NSD3 | c.1394C>A p.P465H | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PARP15 | c.1392C>A p.D464E (on ENST00000464300 / NM_001113523.3; = p.D230E on NM_152615.2) | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RGS5 | c.329C>G p.A110G | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RHPN2 | c.1188G>T p.L396F | Missense Mutation (SNP) | VAF 70/656 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); called by muse, varscan2
- ROR2 | c.1543G>A p.G515R | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.423); called by muse, mutect2
- SEZ6L2 | c.1727A>G p.E576G (on ENST00000308713 / NM_001114099.3; = p.E506G on NM_012410.4) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- SEZ6L2 | c.1726G>A p.E576K (on ENST00000308713 / NM_001114099.3; = p.E506K on NM_012410.4) | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC34A2 | c.1098dup p.I367Hfs*40 | Frame Shift Ins (INS) | VAF 66/543 reads (12%) | called by mutect2, pindel, varscan2
- SPATA31A7 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 18/452 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); called by muse, mutect2
- SRSF9 | c.105C>G p.Y35* | Nonsense Mutation (SNP) | VAF 42/282 reads (15%) | called by muse, varscan2
- TCP11L1 | c.314del p.K105Rfs*12 | Frame Shift Del (DEL) | VAF 18/180 reads (10%) | called by mutect2, varscan2
- TEAD1 | c.166del p.R56Gfs*17 | Frame Shift Del (DEL) | VAF 45/330 reads (14%) | called by mutect2, pindel, varscan2
- TMEM39B | c.503T>A p.L168H | Missense Mutation (SNP) | VAF 42/451 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2
- USF3 | c.2661A>C p.E887D | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.341); called by muse, mutect2
- UTP18 | c.1076A>G p.N359S | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- WBP2 | c.643T>C p.S215P | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR26 | c.814T>C p.W272R (on ENST00000414423 / NM_001379403.1; = p.W172R on NM_025160.7) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF384 | c.1417G>T p.V473L (on ENST00000361959; = p.V412L on NM_133476.5) | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.111); called by muse, varscan2
- ZNF575 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 31/343 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.796); called by muse, mutect2
- CD2AP | c.354G>A p.E118= | Silent (SNP) | VAF 23/284 reads (8%) | called by muse, mutect2
- CLCC1 | c.645T>A p.R215= (on ENST00000356970 / NM_001377464.1; = p.R165= on NM_015127.5) | Silent (SNP) | VAF 38/355 reads (11%) | called by muse, mutect2, varscan2
- DCHS1 | c.4311G>A p.A1437= | Silent (SNP) | VAF 56/616 reads (9%) | catalogued as rs1455260533; called by muse, mutect2
- DOCK6 | c.492C>T p.S164= | Silent (SNP) | VAF 77/588 reads (13%) | catalogued as rs765758751; called by muse, mutect2, varscan2
- FAT3 | c.9360C>T p.I3120= | Silent (SNP) | VAF 16/466 reads (3%) | called by muse, mutect2
- HOXB1 | c.183C>T p.S61= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs748424436, COSV53318812; called by muse, mutect2
- IFIT1 | c.1284G>A p.R428= | Silent (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- MRC2 | c.730C>T p.L244= | Silent (SNP) | VAF 36/302 reads (12%) | called by muse, mutect2, varscan2
- RHOF | c.45G>A p.P15= | Silent (SNP) | VAF 62/493 reads (13%) | catalogued as rs1056011524; called by muse, mutect2, varscan2
- SAGE1 | c.1500T>G p.T500= | Silent (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.897T>C p.C299= (on ENST00000291707 / NM_053003.4; = p.C181= on NM_033329.2) | Silent (SNP) | VAF 21/355 reads (6%) | called by muse, mutect2
- SLC6A20 | c.309C>T p.N103= | Silent (SNP) | VAF 38/284 reads (13%) | catalogued as rs767689740; called by muse, mutect2, varscan2
- TBXAS1 | c.429C>T p.F143= | Silent (SNP) | VAF 73/714 reads (10%) | called by muse, mutect2
- TIMM29 | c.573C>T p.H191= | Silent (SNP) | VAF 56/566 reads (10%) | called by muse, mutect2
- TMEM161B | c.979T>C p.L327= | Silent (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
- AC055839.2 | chr17:5501819 A>G | 5'Flank (SNP) | VAF 53/325 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.3186+33A>C | Intron (SNP) | VAF 38/232 reads (16%) | called by muse, varscan2
- CA8 | c.-24G>A | 5'UTR (SNP) | VAF 45/529 reads (9%) | catalogued as rs1239314442; called by muse, mutect2
- FAS | c.-111G>A | 5'UTR (SNP) | VAF 49/429 reads (11%) | called by muse, mutect2, varscan2
- FCRL5 | c.1681+268A>C | Intron (SNP) | VAF 7/183 reads (4%) | called by muse, mutect2
- GVINP1 | n.5253A>C | RNA (SNP) | VAF 23/219 reads (11%) | called by muse, mutect2
- LIPT2 | chr11:74498009 T>G | 5'Flank (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- MEN1 | c.1065-37C>T | Intron (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- MLIP | c.613-11612C>T | Intron (SNP) | VAF 49/337 reads (15%) | called by muse, mutect2, varscan2
- TCTN1 | c.1332-19T>G | Intron (SNP) | VAF 70/624 reads (11%) | called by muse, mutect2, varscan2
- TMEM106C | c.*62G>T | 3'UTR (SNP) | VAF 31/350 reads (9%) | called by muse, mutect2
